Somatic mutation profile of tumor specimen C3L-06801-54 (aliquot CPT0423330002) from CPTAC case C3L-06801, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 58.3 years (21,287 days).
Specimen C3L-06801-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9c7df13-51ed-4326-a60d-651fa575ac27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06801-51 (Buccal Cell Normal), aliquot CPT0423360001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/960ec695-3627-41a9-bf8c-c875aae0ab0d

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 106/268 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs377577594, COSV53036332, COSV53037241, COSV53063308; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CLTCL1 | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs782113628, COSV99595967; called by muse, mutect2, varscan2
- COL12A1 | c.6859A>G p.K2287E | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs775646975; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMPD1 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 99/285 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV66700481; called by muse, mutect2, varscan2
- FRMPD4 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs779596855, COSV66218014; called by muse, mutect2, varscan2
- KNL1 | c.2749C>T p.R917C (on ENST00000346991 / NM_170589.5; = p.R891C on NM_144508.5) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as rs776523816, COSV100706554; called by muse, mutect2, varscan2
- SHLD3 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs746062019; called by muse, mutect2
- ALAS1 | c.1753T>C p.Y585H | Missense Mutation (SNP) | VAF 118/265 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CREB3L1 | c.645C>G p.D215E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- PRKDC | c.9257T>C p.L3086P | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- USP36 | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- ZNF143 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CFAP46 | c.2478C>T p.S826= | Silent (SNP) | VAF 85/194 reads (44%) | catalogued as rs986025665; called by muse, mutect2, varscan2
- IFI44 | c.249A>G p.Q83= | Silent (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- TRIM67 | c.1146C>T p.N382= | Silent (SNP) | VAF 75/176 reads (43%) | catalogued as rs375674739, COSV64158872; called by muse, mutect2, varscan2
- TRNAU1AP | c.465G>A p.T155= | Silent (SNP) | VAF 96/233 reads (41%) | catalogued as rs776526504, COSV100867933; called by muse, mutect2, varscan2
- AC134312.1 | n.1473G>T | RNA (SNP) | VAF 75/213 reads (35%) | called by muse, mutect2, varscan2
- G6PC3 | c.*259G>A | 3'UTR (SNP) | VAF 53/124 reads (43%) | called by mutect2, varscan2
